Somatic mutation profile of tumor specimen MMRF_2452_1_BM_CD138pos (aliquot MMRF_2452_1_BM_CD138pos_T1_KHS5U_L11250) from MMRF case MMRF_2452, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.4 years (23,508 days).
Specimen MMRF_2452_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff9d3fb5-3e82-4e4d-b2bd-ef4080f6c478.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2452_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2452_1_PB_WBC_C3_KHS5U_L11249; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/203e33d6-2555-4938-8f4f-4b4e3115bf47

The open-access MAF lists 57 somatic variants for this specimen: 21 protein-altering or splice-affecting, 9 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, 3'UTR 15, Silent 9, Intron 6, 5'UTR 3, RNA 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD2 | c.3973G>A p.V1325M | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as rs142169949, COSV53884491; called by muse, mutect2, varscan2
- IGHD3-3 | c.2T>C p.V1A | Missense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as rs546437389; called by muse, mutect2, varscan2
- KRTAP4-4 | c.17G>A p.C6Y | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66811278; called by muse, mutect2, varscan2
- SCN7A | c.1669A>T p.I557F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69274493; called by muse, mutect2, varscan2
- ANKRD6 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANTXR2 | c.1052A>C p.D351A | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- CDR2L | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CYP51A1 | c.1042A>G p.K348E | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- DEF6 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, varscan2
- DOCK7 | c.1780G>C p.D594H | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DSC2 | c.2125+1G>C p.X709_splice | Splice Site (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- IGSF9B | c.112G>T p.G38W | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYPD3 | c.844C>G p.Q282E | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MARS2 | c.1706T>A p.L569Q | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- OR8S1 | c.404T>C p.I135T | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- PTPN6 | c.1582-2A>G p.X528_splice | Splice Site (SNP) | VAF 60/235 reads (26%) | called by muse, varscan2
- SYTL5 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 60/105 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TIAM2 | c.3209A>G p.D1070G | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TLE7 | c.885T>G p.C295W | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TTC6 | c.911T>A p.L304H | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- ZNF875 | c.1163G>T p.R388M | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- DDX55 | c.969G>A p.V323= | Silent (SNP) | VAF 10/82 reads (12%) | called by muse, varscan2
- HOXA2 | c.123G>A p.T41= | Silent (SNP) | VAF 20/199 reads (10%) | catalogued as rs1440265707; called by muse, mutect2
- IGLV3-1 | c.33T>C p.L11= | Silent (SNP) | VAF 67/140 reads (48%) | catalogued as rs528685359; called by muse, mutect2, varscan2
- ITGA9 | c.2845C>T p.L949= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs754317785; called by muse, mutect2, varscan2
- LRRC8D | c.2208G>C p.V736= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as COSV61578472; called by muse, mutect2
- OR7E24 | c.693G>T p.G231= | Silent (SNP) | VAF 34/149 reads (23%) | catalogued as COSV71702203; called by muse, mutect2, varscan2
- PKP4 | c.390G>A p.Q130= | Silent (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2, varscan2
- RRAS2 | c.222G>A p.E74= | Silent (SNP) | VAF 33/301 reads (11%) | called by muse, mutect2, varscan2
- TKTL1 | c.597C>T p.F199= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as rs782244565; called by muse, mutect2, varscan2
- BCLAF1P2 | n.1398G>A | RNA (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- COMT | c.615+248G>A | Intron (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2, varscan2
- CTNS | c.*256C>T | 3'UTR (SNP) | VAF 17/175 reads (10%) | catalogued as rs1258443775; called by muse, mutect2
- DCAF5 | c.879+1731G>A | Intron (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- DNLZ | c.*203C>T | 3'UTR (SNP) | VAF 19/54 reads (35%) | catalogued as rs148566530; called by muse, mutect2, varscan2
- DPP6 | c.-367G>A | 5'UTR (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- FIGN | c.*413A>C | 3'UTR (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- HAND2 | c.*81C>T | 3'UTR (SNP) | VAF 61/385 reads (16%) | called by muse, mutect2, varscan2
- KLHL1 | c.*617A>C | 3'UTR (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- LRCH1 | c.*657C>A | 3'UTR (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- MCFD2 | c.*952C>T | 3'UTR (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- MDM2 | c.359-45C>T | Intron (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.498T>G | RNA (SNP) | VAF 34/133 reads (26%) | called by muse, mutect2, varscan2
- PLA2G2A | c.-79C>T | 5'UTR (SNP) | VAF 34/206 reads (17%) | catalogued as rs1053205338; called by muse, mutect2, varscan2
- RAP1GDS1 | c.*1539A>C | 3'UTR (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- RWDD4 | c.*447C>G | 3'UTR (SNP) | VAF 53/404 reads (13%) | called by muse, mutect2, varscan2
- SEMA3E | c.*781dup | 3'UTR (INS) | VAF 24/120 reads (20%) | catalogued as rs148414428; called by mutect2, varscan2
- SKIDA1 | c.*443G>A | 3'UTR (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
- SLMAP | c.1336+896A>G | Intron (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- SYBU | c.*68T>C | 3'UTR (SNP) | VAF 74/271 reads (27%) | called by muse, varscan2
- TBC1D30 | c.*2076C>T | 3'UTR (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- TNIP1 | c.1876+80G>A | Intron (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- TRIP13 | c.*784G>A | 3'UTR (SNP) | VAF 8/51 reads (16%) | catalogued as rs1392694970; called by muse, mutect2, varscan2
- TTC17 | c.774-49C>A | Intron (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- VSTM2L | c.*885C>T | 3'UTR (SNP) | VAF 17/79 reads (22%) | catalogued as rs887346791; called by muse, mutect2, varscan2
- ZCCHC9 | c.-2178A>G | 5'UTR (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- ZNF861P | n.512G>C | RNA (SNP) | VAF 20/120 reads (17%) | called by muse, mutect2, varscan2
